Surgical pathology report (de-identified scan), TCGA case TCGA-49-4505, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4505-01A (Primary Tumor).

[REDACTED]

FINAL DIAGNOSIS ----- [REDACTED]

RIGHT LOWER LOBE, LUNG (LOBECTOMY): INFILTRATING WELL
DIFFERENTIATED ADENOCARCINOMA. THE CARCINOMA MEASURES 5.5 CM IN
GREATEST DIMENSION AND EXTENDS THROUGH THE VISCERAL PLEURA. METASTATIC
CARCINOMA IN ONE (1) OF SIX (6) LYMPH NODES. THE BRONCHIAL AND
VASCULAR MARGINS ARE NEGATIVE FOR TUMOR. SEE NOTE.

BRONCHIAL MARGIN (BX): NEGATIVE FOR TUMOR.

11 R LYMPH NODE (BX): METASTATIC ADENOCARCINOMA IN ONE (1) LYMPH
NODE.

LUNG, RIGHT UPPER LOBE (WEDGE RESECTION): CAVITARY FIBROTIC CYST
COLONIZED BY BRANCHING HYPHAL FUNGAL FORMS MORPHOLOGICALLY CONSISTENT
WITH ASPERGILLUS. NEGATIVE FOR TUMOR.

LUNG, RIGHT UPPER LOBE (WEDGE RESECTION): INFILTRATING WELL
DIFFERENTIATED ADENOCARCINOMA. THE CARCINOMA MEASURES 1.5 CM IN

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file dd5b1b1e-7b61-4a52-b391-0d3aabd49c2e (TCGA-49-4505.1733D182-08F0-4426-9227-9F008893AC14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).